MMRF case MMRF_1921 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1d056d83-18b9-4d28-b1e8-91345a433963

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.7 years (22,546 days); ISS stage: I; Days to last known disease status: 1,007 days (2.8 years); Days to last follow up: 1,007 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 419 days (1.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 34 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 34 days; Days to treatment end: 207 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 221 days; Days to treatment end: 221 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 222 days; Days to treatment end: 222 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 419 days (1.1 years).
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 724 days (2.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 1): M Protein 3.66 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.938 mg/dL; Immunoglobulin G 41.5 g/L; Immunoglobulin A 1.2 g/L; Immunoglobulin M 0.89 g/L; Beta 2 Microglobulin 2.6 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 10.1 g/dL; Glucose 5.89 mmol/L; C-Reactive Protein 0.07 mg/dL.
- Day 97 (ECOG 0): M Protein 1.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.502 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.08 mg/dL; Immunoglobulin G 16.8 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.61 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 5.12 mmol/L.
- Day 181 (ECOG 0): M Protein 1.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.617 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.494 mg/dL; Immunoglobulin G 17 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.75 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 5.45 mmol/L.
- Day 250 (ECOG 0): M Protein 0.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.909 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 1 g/L; Lactate Dehydrogenase 3.65 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 4.64 ×10⁹/L; Platelets 289 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 4.79 mmol/L.
- Day 349 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.824 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 1.66 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 5.17 mmol/L.
- Day 433 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 1.82 g/L; Immunoglobulin M 1.07 g/L; Lactate Dehydrogenase 3.77 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 5.61 mmol/L.
- Day 545 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.987 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.58 mg/dL; Immunoglobulin G 9.97 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7.2 g/dL; Glucose 5.78 mmol/L.
- Day 629 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.598 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Glucose 4.57 mmol/L.
- Day 699 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.928 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 1.44 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 5.72 mmol/L.
- Day 818 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.5 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 3.47 mmol/L.
- Day 916 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.54 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 46 g/L; Total Protein 7.2 g/dL; Glucose 6.11 mmol/L.
- Day 1,007: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.06 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 1.79 g/L; Immunoglobulin M 0.59 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day -9: Weight: 85 kg; Height: 177 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1921_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_1921_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
